Somatic mutation profile of tumor specimen MP2PRT-PARRLP-TMP1-A (aliquot MP2PRT-PARRLP-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARRLP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (898 days).
Specimen MP2PRT-PARRLP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73606f01-fc47-4c14-a154-7aeb34e737ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRLP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRLP-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20890262-dc00-42c7-9ed0-faf5407aa29f

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 174/615 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854556, CM000802, CM983421, COSV100648616, COSV62196628, COSV62224419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 211/504 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD18B | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 90/302 reads (30%) | catalogued as rs1157623873, COSV99340463; called by muse, mutect2, varscan2
- ARHGEF10L | c.3688G>A p.A1230T | Missense Mutation (SNP) | VAF 134/692 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs747444357, COSV51428066; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 113/525 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUB1B | c.650_651del p.F217* | Frame Shift Del (DEL) | VAF 188/493 reads (38%) | called by mutect2, pindel*, varscan2*
- PTCH1 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 169/398 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- NEDD4 | c.3897A>G p.E1299= (on ENST00000508342 / NM_001284338.1; = p.E880= on NM_006154.4) | Silent (SNP) | VAF 72/306 reads (24%) | called by muse, mutect2, varscan2
